MMRF case MMRF_1633 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b817d3c9-6b5b-4ef9-b46f-02bf9d334f80

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.3 years (19,842 days); ISS stage: III; Days to last known disease status: 247 days; Days to last follow up: 247 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 247.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 325 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 2.36 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 19.1 µg/mL; Lactate Dehydrogenase 9.89 µkat/L; Hemoglobin 3.41 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 162 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 3.68 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 12.9 mg/dL.
- Day 98 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 32.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.635 mg/dL; Immunoglobulin G 5.84 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 7.97 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.94 mmol/L.
- Day 168 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.762 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 7.48 mmol/L.

Other clinical attributes
- Day -2: Weight: 110 kg; Height: 152 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1633_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1633_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
